Gene-level copy-number profile of tumor specimen HCM-BROD-0421-C71-01B from HCMI case HCM-BROD-0421-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.7 years (18,165 days).
Specimen HCM-BROD-0421-C71-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1b80ae38-3478-40f2-8c70-3f028093e5d6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0421-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/5998acfe-0c74-4dc2-abde-8497bb5df1b6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 12; copy number 2: 677; copy number 3: 7,027; copy number 4: 20,188; copy number 5: 7,749; copy number 6: 13,885; copy number 7: 5,030; copy number 8: 3,034; copy number 9: 614; copy number 11: 2; copy number 12: 5; copy number 18: 5; copy number 35: 92; copy number 129: 17; copy number 134: 19; copy number 140: 3; copy number 144: 4.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–4): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr5:120,245,448–120,790,778, 7 genes: AC008574.1, RNU6-718P, AC113418.1, PRR16, PRELID3BP8, RNU4-69P, AC114284.1.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr10:79,703,227–79,714,681, 1 gene (within-gene range 0–3): NUTM2B.
- chr15:21,990,074–22,152,897, 11 genes (within-gene range 0–5): AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P, OR4H6P, OR4M2, OR4N4, OR4N3P, AC010760.1, RPS8P10.
- chr15:34,489,002–34,521,791, 3 genes: HNRNPLP2, FSCN1P1, DNM1P5.
- chr15:34,528,290–34,528,371, 1 gene (within-gene range 0–8): MIR1233-2.
- chr17:18,426,861–18,442,895, 2 genes: KRT17P2, KRT16P1.
- chr17:18,452,955–18,453,739, 2 genes (within-gene range 0–1): AL353997.1, AL353997.4.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 761 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:154,548,577–157,237,136, 144 genes, copy number 9 (broad region; genes not listed).
- chr4:51,843,000–56,435,615, 92 genes, copy number 35 (broad region; genes not listed).
- chr6:905,445–1,104,946, 4 genes, copy number 9: AL356130.1, LINC01622, AL033381.2, AL033381.1.
- chr6:120,015,179–120,781,512, 5 genes, copy number 18: MIR3144, AL096854.1, RNU6-214P, RNA5SP215, COX6A1P3.
- chr8:7,715,443–7,896,716, 18 genes, copy number 9: FAM90A14P, FAM90A18P, FAM90A16P, FAM90A8P, FAM90A17P, FAM90A19P, FAM90A9P, FAM90A10P, PRR23D2, PRR23D3P, DEFB107A, DEFB105A, DEFB106A, DEFB104A, SPAG11A, DEFB103A, HSPD1P2, DEFB4A.
- chr9:41,340,823–41,355,538, 1 gene, copy number 11: CDRT15P6.
- chr9:64,621,560–64,889,063, 9 genes, copy number 9: AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2, BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P.
- chr9:121,815,674–121,819,452, 1 gene, copy number 11: AL596244.1.
- chr10:60,734,342–61,026,420, 5 genes, copy number 12: ANK3-DT, CDK1, RHOBTB1, RNU2-72P, LINC00845.
- chr12:45,444,766–45,610,620, 3 genes, copy number 140: AC063924.1, AC079950.1, U6.
- chr12:52,585,589–52,782,839, 17 genes, copy number 129: KRT72, KRT73-AS1, KRT73, KRT128P, KRT2, KRT1, KRT77, AC055716.3, KRT126P, KRT125P, AC055716.2, AC055716.1, BTBD10P1, KRT127P, ARL2BPP2, KRT76, AC107016.2.
- chr12:57,723,761–57,896,482, 19 genes, copy number 134 (within-gene range 5–134): AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1.
- chr12:123,233,436–123,283,034, 4 genes, copy number 144 (within-gene range 5–144): C12orf65, CDK2AP1, AC068768.1, RNA5SP375.
- chr20:7,069,614–22,746,991, 230 genes, copy number 9 (broad region; genes not listed).
- chr22:15,282,557–20,070,965, 209 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 12. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
